Somatic mutation profile of tumor specimen MMRF_1193_5_BM_CD138pos (aliquot MMRF_1193_5_BM_CD138pos_T1_KHS5U_K15213) from MMRF case MMRF_1193, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.0 years (23,023 days).
Specimen MMRF_1193_5_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7548493-cf2e-487c-b570-38cc11deff37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1193_3_PB_Whole (Blood Derived Normal), aliquot MMRF_1193_3_PB_Whole_C3_KBS5U_L05827; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0b11c00-2254-446d-954a-7dba8e4d18d0

The open-access MAF lists 620 somatic variants for this specimen: 211 protein-altering or splice-affecting, 74 silent, 335 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 188, 3'UTR 160, Intron 82, Silent 74, 5'UTR 47, 5'Flank 20, 3'Flank 16, Nonsense Mutation 15, RNA 10, Splice Region 5, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANK1 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 12/118 reads (10%) | hotspot (GDC flag); catalogued as rs202109621, COSV64160606; called by muse, mutect2
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 67/94 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHDC1 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1250394860, COSV55937179; called by muse, mutect2, varscan2
- AIM2 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 67/261 reads (26%) | catalogued as rs1052080482, COSV63700597; called by muse, mutect2, varscan2
- AKR1C4 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1367695039, COSV99578619; called by muse, mutect2
- ALOX5 | c.1309G>A p.V437M | Missense Mutation (SNP) | VAF 82/165 reads (50%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.892); catalogued as rs1384941753; called by muse, mutect2, varscan2
- ANKRD18B | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs368272098; called by muse, mutect2, varscan2
- ARPP21 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.152); catalogued as COSV99492383; called by muse, mutect2, varscan2
- ATOH1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as rs745424790; called by muse, mutect2
- ATP10B | c.3587G>A p.W1196* | Nonsense Mutation (SNP) | VAF 11/299 reads (4%) | catalogued as COSV59159695; called by muse, mutect2
- B4GALT6 | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 100/204 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1413191387; called by muse, mutect2, varscan2
- BICC1 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100874850, COSV100874863; called by muse, mutect2, varscan2
- C5 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.156); catalogued as rs758284368; called by muse, mutect2, varscan2
- CACNA1C | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758229132, COSV59768190; called by muse, mutect2
- CAND1 | c.2356C>T p.Q786* | Nonsense Mutation (SNP) | VAF 101/219 reads (46%) | catalogued as COSV73389775; called by muse, mutect2, varscan2
- CDH9 | c.2048G>A p.R683K | Missense Mutation (SNP) | VAF 151/317 reads (48%) | SIFT tolerated (0.81); PolyPhen benign (0.216); catalogued as COSV50271655; called by muse, mutect2, varscan2
- CDH9 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 89/227 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs1190956402, COSV99142545, COSV99163558; called by muse, mutect2, varscan2
- CEACAM6 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV52267309; called by muse, varscan2
- CEP95 | c.358C>A p.H120N | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.107); catalogued as COSV73609603; called by muse, mutect2, varscan2
- CFAP47 | c.5399G>A p.G1800E | Missense Mutation (SNP) | VAF 54/59 reads (92%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV57970939; called by muse, mutect2, varscan2
- CNTN6 | c.3044T>G p.V1015G | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV63166323; called by muse, mutect2, varscan2
- COL4A1 | c.2552C>T p.P851L | Missense Mutation (SNP) | VAF 68/70 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1330645218; called by muse, mutect2, varscan2
- COL5A3 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 64/117 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV53409186, COSV99318981; called by muse, mutect2, varscan2
- CPNE6 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs747176281, COSV53743323; called by muse, mutect2, varscan2
- CTSW | c.955C>G p.Q319E | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV57173455; called by muse, mutect2, varscan2
- DLGAP2 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs894944884; called by muse, mutect2, varscan2
- DNMT3L | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV54266651; called by muse, mutect2, varscan2
- FAM47A | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs373924083, COSV60498900; called by muse, mutect2
- FCRL3 | c.717G>T p.W239C | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as COSV100943019; called by muse, mutect2, varscan2
- FFAR1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142645954; called by muse, mutect2, varscan2
- FIZ1 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV55609134; called by muse, mutect2
- FLG2 | c.4920G>C p.Q1640H | Missense Mutation (SNP) | VAF 22/616 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV66166665; called by muse, mutect2
- FLNB | c.4813C>T p.R1605C | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs745461413; called by muse, mutect2, varscan2
- FLRT2 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV58142228; called by muse, mutect2, varscan2
- FNDC7 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV54753347; called by muse, mutect2, varscan2
- H2AC13 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1173823415; called by muse, mutect2, varscan2
- HCFC1R1 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.124); catalogued as rs762463939, COSV50187156, COSV99560786; called by muse, mutect2, varscan2
- HPGDS | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs754130316, COSV99756190; called by muse, mutect2, varscan2
- HSD11B1L | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.306); catalogued as rs979572712; called by muse, mutect2, varscan2
- IGKV4-1 | c.124A>C p.N42H | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs374920058; called by muse, mutect2, varscan2
- IGLV4-60 | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 74/82 reads (90%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as rs567826008, COSV101135244; called by muse, mutect2, varscan2
- IGLV5-45 | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 72/80 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as rs771901307; called by muse, mutect2, varscan2
- IGLV7-43 | c.272A>C p.K91T | Missense Mutation (SNP) | VAF 78/86 reads (91%) | SIFT tolerated (0.49); PolyPhen probably damaging (1); catalogued as rs753162507; called by muse, mutect2, varscan2
- IGLV7-46 | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 60/68 reads (88%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760223538; called by muse, mutect2
- KCNT2 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1432879941; called by muse, mutect2, varscan2
- KLF2 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50179793; called by muse, mutect2
- KLRG2 | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as rs1373731577; called by muse, mutect2
- KRTCAP2 | c.159+8C>T | Splice Region (SNP) | VAF 172/272 reads (63%) | catalogued as rs745330956; called by muse, mutect2, varscan2
- LRFN5 | c.318G>C p.L106F | Missense Mutation (SNP) | VAF 67/127 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53245253; called by muse, mutect2, varscan2
- MEI1 | c.3167C>T p.S1056L | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as rs745507394, COSV100300122, COSV55905477; called by muse, mutect2, varscan2
- MYOCD | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs1453556592; called by muse, mutect2
- MZB1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs1281446943; called by muse, mutect2, varscan2
- NAV2 | c.7429G>A p.D2477N (on ENST00000396087 / NM_001244963.2; = p.D2418N on NM_145117.5) | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs376495913; called by muse, mutect2, varscan2
- NCF4 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as rs756372095; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEK1 | c.215-1G>A p.X72_splice | Splice Site (SNP) | VAF 66/126 reads (52%) | catalogued as rs1207752590; called by muse, mutect2, varscan2
- NEO1 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1394017297; called by muse, mutect2, varscan2
- NKPD1 | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs758655376, COSV100521578; called by muse, mutect2, varscan2
- NOTCH4 | c.5378G>A p.R1793Q | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1210630301, COSV66679301, COSV66683180; called by muse, mutect2
- NPR1 | c.3091G>C p.E1031Q | Missense Mutation (SNP) | VAF 28/457 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.02); catalogued as rs369076763; called by muse, mutect2
- NYNRIN | c.4640C>T p.S1547F | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs770129632; called by muse, mutect2, varscan2
- OR51S1 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59060458; called by muse, mutect2, varscan2
- PCDHA6 | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV65342335, COSV65343616; called by muse, mutect2
- PCDHGA10 | c.1579G>C p.E527Q | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53996462; called by muse, mutect2, varscan2
- PGM3 | c.389+6G>A | Splice Region (SNP) | VAF 16/145 reads (11%) | catalogued as rs1478742693; called by muse, mutect2, varscan2
- PODXL2 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV61065919; called by muse, mutect2, varscan2
- POLR2L | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.318); catalogued as COSV58990383, COSV58990492; called by muse, mutect2
- POT1 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 75/75 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62930062; called by muse, mutect2, varscan2
- PRKDC | c.8590C>T p.Q2864* | Nonsense Mutation (SNP) | VAF 57/138 reads (41%) | catalogued as COSV58058534; called by muse, mutect2, varscan2
- RADIL | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs778018782; called by mutect2, varscan2
- RIMS1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104393426; called by muse, mutect2
- RPGRIP1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52850356; called by muse, mutect2
- SAMD11 | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as COSV58988370; called by muse, mutect2, varscan2
- SCAMP2 | c.853C>G p.R285G | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV51512258; called by muse, mutect2, varscan2
- SETD2 | c.4582G>A p.E1528K | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100338473, COSV57452009; called by muse, mutect2, varscan2
- SKI | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1290478159; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMIM17 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.617); catalogued as rs779060450; called by muse, mutect2
- SOX8 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs1320093608; called by muse, mutect2, varscan2
- STAG1 | c.2443C>T p.Q815* | Nonsense Mutation (SNP) | VAF 42/86 reads (49%) | catalogued as COSV52619133; called by muse, mutect2, varscan2
- SUCO | c.3509C>T p.S1170L | Missense Mutation (SNP) | VAF 105/328 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs1307525856, COSV55264582; called by muse, mutect2, varscan2
- SYNJ2 | c.3729G>C p.L1243F | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.025); catalogued as rs770957876; called by muse, mutect2, varscan2
- TESC | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.105); catalogued as rs780004006; called by muse, mutect2, varscan2
- TET2 | c.5620G>A p.E1874K | Missense Mutation (SNP) | VAF 72/128 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54407170, COSV54407217; called by muse, mutect2, varscan2
- THBS2 | c.1880G>C p.R627T | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.86); PolyPhen benign (0.196); catalogued as COSV64682742; called by muse, mutect2, varscan2
- TNFRSF21 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs867596127, COSV57279933; called by muse, mutect2, varscan2
- TRIM36 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs772306724; called by muse, mutect2, varscan2
- TSN | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0.021); catalogued as COSV67605238, COSV67605459; called by muse, mutect2, varscan2
- TTN | c.24214C>G p.L8072V (on ENST00000591111; = p.L7145V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/272 reads (7%) | PolyPhen benign (0.012); catalogued as COSV59877868; called by muse, mutect2
- TTN | c.7228C>G p.H2410D (on ENST00000591111; = p.H2364D on NM_003319.4) | Missense Mutation (SNP) | VAF 111/237 reads (47%) | PolyPhen possibly damaging (0.83); catalogued as COSV60041627; called by muse, mutect2, varscan2
- VIRMA | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 176/359 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV52591336; called by muse, mutect2, varscan2
- XRN1 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as COSV99378738; called by muse, mutect2, varscan2
- ZIC2 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 201/218 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV100891762, COSV66255273; called by muse, mutect2, varscan2
- ZNF121 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.911); catalogued as rs753972854, COSV100248251; called by muse, mutect2, varscan2
- ZNF285 | c.1060G>C p.G354R | Missense Mutation (SNP) | VAF 135/278 reads (49%) | SIFT tolerated (0.82); PolyPhen benign (0.338); catalogued as COSV58408515; called by muse, mutect2, varscan2
- ZNF773 | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 93/244 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1348705230, COSV56588832; called by muse, mutect2, varscan2
- ZSCAN10 | c.955C>T p.R319C (on ENST00000252463; = p.R374C on NM_032805.3) | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772666527, COSV52967602; called by muse, mutect2, varscan2
- ABCC5 | c.4108G>C p.E1370Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ACSS2 | c.1902G>A p.Q634= | Splice Region (SNP) | VAF 65/129 reads (50%) | called by muse, mutect2, varscan2
- ADAMTS14 | c.3304C>T p.P1102S | Missense Mutation (SNP) | VAF 112/255 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAMTS19 | c.3567G>C p.Q1189H | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ADGRV1 | c.4793G>A p.R1598K | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFM | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- AGRN | c.5911G>A p.E1971K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- AMIGO2 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 120/229 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- ANK1 | c.4434G>T p.E1478D | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKAR | c.1159G>C p.D387H | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO6 | c.197A>C p.Q66P | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ANO7 | c.637C>T p.P213S (on ENST00000274979; = p.P159S on NM_001370694.2) | Missense Mutation (SNP) | VAF 136/292 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- AS3MT | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 114/251 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ASB14 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 120/268 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ASIC4 | c.556C>G p.H186D | Missense Mutation (SNP) | VAF 72/137 reads (53%) | SIFT tolerated (0.56); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- ATP2B1 | c.3338G>C p.R1113T | Missense Mutation (SNP) | VAF 52/60 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- ATP2B4 | c.1615C>G p.L539V | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- C16orf89 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C4orf17 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 173/359 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- C6 | c.864G>C p.K288N | Missense Mutation (SNP) | VAF 11/311 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.28); called by muse, mutect2
- CACNG8 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CADPS | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CCDC173 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC74A | c.295+3G>A | Splice Region (SNP) | VAF 42/86 reads (49%) | called by muse, mutect2, varscan2
- CCT4 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 116/280 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- CDX4 | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 33/35 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP162 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHUK | c.2039C>T p.S680L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CLSTN2 | c.419dup p.S141Vfs*36 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- CMYA5 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CNTLN | c.2344A>C p.N782H | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- COL7A1 | c.2675G>A p.R892K | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CPEB1 | c.385G>A p.E129K (on ENST00000617958; = p.E69K on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/203 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- CSNK2A2 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTNNA3 | c.2649G>T p.L883F | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DDX50 | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DMXL2 | c.3736C>T p.P1246S | Missense Mutation (SNP) | VAF 142/334 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH1 | c.9328G>A p.E3110K | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DYNC2H1 | c.2962C>G p.Q988E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEF1G | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0.178); called by muse, mutect2
- EEF2 | c.1606-3C>T | Splice Region (SNP) | VAF 91/222 reads (41%) | called by muse, mutect2, varscan2
- EPG5 | c.6029C>T p.S2010L | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERI2 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAM111B | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- FAM222B | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FAM8A1 | c.769T>G p.F257V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FBXW12 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- FNDC3A | c.1076C>A p.S359* (on ENST00000492622 / NM_001079673.2; = p.S303* on NM_014923.5) | Nonsense Mutation (SNP) | VAF 79/88 reads (90%) | called by muse, mutect2, varscan2
- GDI2 | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- GTF3C2 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 37/91 reads (41%) | called by muse, mutect2, varscan2
- HECW2 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ITPR3 | c.5294A>C p.N1765T | Missense Mutation (SNP) | VAF 83/173 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- KALRN | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); called by muse, mutect2
- KDM5C | c.4106C>G p.S1369* | Nonsense Mutation (SNP) | VAF 109/116 reads (94%) | called by muse, mutect2, varscan2
- KIAA2026 | c.6155G>C p.G2052A | Missense Mutation (SNP) | VAF 96/181 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF5C | c.621T>A p.S207R | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT5C | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- KRT39 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP2 | c.4685G>A p.R1562K | Missense Mutation (SNP) | VAF 73/137 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LRRC8A | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 96/409 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- MACF1 | c.5528C>A p.A1843D | Missense Mutation (SNP) | VAF 37/92 reads (40%) | called by muse, mutect2, varscan2
- MBLAC2 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCUB | c.133T>G p.Y45D | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP11 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- MUC22 | c.2761G>T p.E921* | Nonsense Mutation (SNP) | VAF 357/779 reads (46%) | called by muse, mutect2, varscan2
- NCKAP1 | c.3134C>G p.T1045R | Missense Mutation (SNP) | VAF 75/201 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NDST3 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- NFIL3 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 135/290 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NOX4 | c.1485G>T p.Q495H | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- NRAS | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 139/146 reads (95%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- NRDC | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- NSMF | c.850G>A p.E284K (on ENST00000371475 / NM_001130969.3; = p.E282K on NM_015537.4) | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NUP133 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 144/233 reads (62%) | SIFT tolerated (0.32); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- NXN | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 87/206 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR13C5 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- PBXIP1 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PCDH7 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PKP2 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- PLCB4 | c.2528C>T p.S843L | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- POU5F1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PPP4R1 | c.1052G>C p.R351T (on ENST00000400556 / NM_001042388.3; = p.R334T on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRPF4B | c.1179G>C p.K393N | Missense Mutation (SNP) | VAF 96/199 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PSMC5 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.24); called by muse, mutect2
- PUS10 | c.929G>C p.G310A | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RALGAPA1 | c.4603G>T p.E1535* | Nonsense Mutation (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- ROBO2 | c.3508G>A p.D1170N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- RPL5 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RYR2 | c.3115G>A p.D1039N | Missense Mutation (SNP) | VAF 78/244 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SARAF | c.192G>T p.L64F | Missense Mutation (SNP) | VAF 101/200 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCN3B | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 91/192 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- SELENOO | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- SERPINB7 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- SLC12A2 | c.2036C>G p.S679* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- SMC5 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- SMG1 | c.6172C>T p.P2058S | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SPATA7 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- SRSF2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 151/297 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- TGDS | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- TMEM59 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 76/145 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- TMX4 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 103/192 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRMT1 | c.488C>G p.S163* | Nonsense Mutation (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- TRPA1 | c.2296-1G>A p.X766_splice | Splice Site (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- TSC22D1 | c.1634C>T p.S545L | Missense Mutation (SNP) | VAF 79/89 reads (89%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TTC9 | c.118G>C p.A40P | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- TTK | c.2045C>T p.S682F | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- UNC13B | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- XPNPEP3 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 149/313 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- YTHDF2 | c.1249A>T p.S417C | Missense Mutation (SNP) | VAF 112/267 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFHX2 | c.614G>C p.G205A | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- ZMYM6 | c.471G>C p.E157D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ZNF132 | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF326 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF467 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 58/70 reads (83%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ZNF696 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.236); called by muse, mutect2
- ZNF749 | c.1804C>A p.H602N | Missense Mutation (SNP) | VAF 98/202 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- ZNF823 | c.311G>C p.G104A (on ENST00000341191 / NM_001297610.2; = p.G60A on NM_017507.2) | Missense Mutation (SNP) | VAF 196/418 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADGRG3 | c.234G>A p.L78= | Silent (SNP) | VAF 55/117 reads (47%) | called by muse, mutect2, varscan2
- ANKRD33B | c.843G>A p.Q281= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- ASIP | c.384C>T p.L128= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs1226395280; called by muse, mutect2, varscan2
- ASPM | c.7269G>C p.V2423= | Silent (SNP) | VAF 76/232 reads (33%) | called by muse, mutect2, varscan2
- ATAD3C | c.45G>A p.T15= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs764063801; called by muse, mutect2, varscan2
- AWAT1 | c.39G>A p.L13= | Silent (SNP) | VAF 93/99 reads (94%) | called by muse, mutect2, varscan2
- BHLHE22 | c.774G>A p.L258= | Silent (SNP) | VAF 63/128 reads (49%) | called by muse, mutect2, varscan2
- BLOC1S5 | c.240G>A p.K80= | Silent (SNP) | VAF 37/91 reads (41%) | called by muse, mutect2, varscan2
- C1orf185 | c.345C>T p.I115= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as rs1221222503, COSV65624222; called by muse, mutect2
- CACNA2D3 | c.2418C>T p.L806= | Silent (SNP) | VAF 10/157 reads (6%) | catalogued as COSV99878157; called by muse, mutect2
- CAPN5 | c.351G>A p.Q117= (on ENST00000456580; = p.Q77= on NM_004055.5) | Silent (SNP) | VAF 59/128 reads (46%) | catalogued as rs782631999; called by muse, mutect2, varscan2
- CENPB | c.141G>A p.K47= | Silent (SNP) | VAF 118/288 reads (41%) | called by muse, mutect2, varscan2
- CHST10 | c.537G>A p.L179= | Silent (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- CNKSR1 | c.48G>A p.L16= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as COSV64164457; called by muse, mutect2, varscan2
- CNTRL | c.5145G>A p.L1715= | Silent (SNP) | VAF 64/225 reads (28%) | called by muse, mutect2, varscan2
- COL6A1 | c.690G>A p.Q230= | Silent (SNP) | VAF 96/184 reads (52%) | called by muse, mutect2, varscan2
- DFFA | c.876G>A p.E292= | Silent (SNP) | VAF 83/175 reads (47%) | catalogued as rs778099664; called by muse, mutect2, varscan2
- DMRT1 | c.204G>A p.K68= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as rs1041963561; called by muse, mutect2, varscan2
- DYRK1B | c.645G>A p.R215= | Silent (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- ETS2 | c.501C>T p.I167= | Silent (SNP) | VAF 55/139 reads (40%) | called by muse, mutect2, varscan2
- FAR1 | c.1431C>T p.L477= | Silent (SNP) | VAF 104/218 reads (48%) | called by muse, mutect2, varscan2
- FEZF2 | c.630C>T p.L210= | Silent (SNP) | VAF 43/102 reads (42%) | called by muse, mutect2, varscan2
- GJA1 | c.636C>T p.F212= | Silent (SNP) | VAF 86/235 reads (37%) | called by muse, mutect2, varscan2
- GPR63 | c.957C>G p.L319= | Silent (SNP) | VAF 67/137 reads (49%) | catalogued as COSV57741468; called by muse, mutect2, varscan2
- HELZ2 | c.1155C>T p.F385= | Silent (SNP) | VAF 64/121 reads (53%) | catalogued as rs140900015; called by muse, mutect2, varscan2
- HGSNAT | c.1854C>G p.L618= | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- HSD17B1 | c.120G>A p.L40= | Silent (SNP) | VAF 43/194 reads (22%) | called by muse, mutect2, varscan2
- HTRA2 | c.486C>G p.V162= | Silent (SNP) | VAF 58/175 reads (33%) | called by muse, mutect2, varscan2
- HTT | c.5781G>A p.L1927= | Silent (SNP) | VAF 114/232 reads (49%) | catalogued as COSV61864997, COSV61865531; called by muse, mutect2, varscan2
- JAGN1 | c.48C>T p.D16= | Silent (SNP) | VAF 51/111 reads (46%) | called by muse, mutect2, varscan2
- KANK2 | c.1092G>A p.L364= | Silent (SNP) | VAF 49/110 reads (45%) | catalogued as COSV62008734; called by muse, mutect2, varscan2
- KHDC3L | c.309C>A p.I103= | Silent (SNP) | VAF 11/116 reads (9%) | catalogued as rs890420715; called by muse, mutect2
- LSR | c.1908C>T p.L636= (on ENST00000361790; = p.L617= on NM_015925.6) | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as rs1041073627, COSV55887035; called by muse, mutect2, varscan2
- MAGI1 | c.249C>T p.R83= | Silent (SNP) | VAF 86/179 reads (48%) | called by muse, mutect2, varscan2
- MAST4 | c.3564G>A p.L1188= (on ENST00000403625 / NM_001164664.2; = p.L999= on NM_015183.3) | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV55120818; called by muse, mutect2, varscan2
- MTG1 | c.246C>G p.L82= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV53375322; called by muse, mutect2, varscan2
- NCF2 | c.387C>T p.F129= | Silent (SNP) | VAF 88/300 reads (29%) | called by muse, mutect2, varscan2
- NECTIN1 | c.966C>T p.I322= | Silent (SNP) | VAF 53/121 reads (44%) | catalogued as rs774045034, COSV50608548; called by muse, mutect2, varscan2
- NHSL1 | c.4224G>A p.S1408= | Silent (SNP) | VAF 55/61 reads (90%) | called by muse, mutect2, varscan2
- NR4A2 | c.1605C>T p.L535= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as COSV59895965; called by muse, mutect2, varscan2
- PADI1 | c.1404C>T p.L468= | Silent (SNP) | VAF 79/175 reads (45%) | catalogued as rs1422659153, COSV100969221; called by muse, mutect2, varscan2
- PAPPA | c.4764G>A p.V1588= | Silent (SNP) | VAF 25/166 reads (15%) | called by muse, mutect2, varscan2
- PARD3B | c.3396C>T p.L1132= (on ENST00000406610 / NM_001302769.2; = p.L1063= on NM_057177.7) | Silent (SNP) | VAF 50/167 reads (30%) | called by muse, mutect2, varscan2
- PGM1 | c.936C>T p.V312= | Silent (SNP) | VAF 50/134 reads (37%) | called by muse, mutect2, varscan2
- PKD1L3 | c.4335C>T p.F1445= | Silent (SNP) | VAF 25/133 reads (19%) | catalogued as rs1283370135; called by muse, mutect2, varscan2
- PRTG | c.3258C>T p.I1086= | Silent (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- RAB13 | c.72G>A p.L24= | Silent (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2, varscan2
- RET | c.489G>C p.R163= | Silent (SNP) | VAF 152/420 reads (36%) | called by muse, mutect2, varscan2
- RGS1 | c.54C>T p.F18= | Silent (SNP) | VAF 311/464 reads (67%) | catalogued as COSV66505354; called by muse, mutect2, varscan2
- RNF151 | c.183G>A p.V61= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs1214219877; called by muse, mutect2, varscan2
- RPL30 | c.333G>A p.Q111= | Silent (SNP) | VAF 20/182 reads (11%) | catalogued as rs201910608; called by muse, mutect2
- RSPH10B | c.444G>A p.T148= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs762338320; called by muse, varscan2
- RUFY1 | c.153G>A p.R51= | Silent (SNP) | VAF 45/132 reads (34%) | catalogued as rs995180258, COSV60162067; called by muse, mutect2, varscan2
- SCG2 | c.1791C>T p.L597= | Silent (SNP) | VAF 19/202 reads (9%) | catalogued as COSV59538863, COSV59538870; called by muse, mutect2, varscan2
- SH3D21 | c.2079G>T p.L693= (on ENST00000453908 / NM_001162530.2; = p.L582= on NM_024676.5) | Silent (SNP) | VAF 49/103 reads (48%) | called by muse, mutect2, varscan2
- SLC33A1 | c.357C>T p.F119= | Silent (SNP) | VAF 63/159 reads (40%) | called by muse, mutect2, varscan2
- SMKR1 | c.48G>A p.G16= | Silent (SNP) | VAF 120/267 reads (45%) | called by muse, varscan2
- SMS | c.486C>T p.L162= | Silent (SNP) | VAF 75/82 reads (91%) | catalogued as COSV65114057; called by muse, mutect2, varscan2
- SPACA3 | c.150C>T p.A50= | Silent (SNP) | VAF 64/141 reads (45%) | catalogued as rs371593939; called by muse, mutect2, varscan2
- SPATA32 | c.408C>T p.F136= | Silent (SNP) | VAF 90/187 reads (48%) | catalogued as COSV59303160, COSV59304029; called by muse, mutect2, varscan2
- SPTA1 | c.6900G>C p.L2300= | Silent (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- TEKT3 | c.798G>A p.R266= | Silent (SNP) | VAF 86/212 reads (41%) | catalogued as rs559365716; called by muse, mutect2, varscan2
- TNFSF14 | c.708G>T p.G236= | Silent (SNP) | VAF 198/449 reads (44%) | called by muse, mutect2, varscan2
- TRIM24 | c.606C>T p.V202= | Silent (SNP) | VAF 64/67 reads (96%) | called by muse, mutect2, varscan2
- TRIM77 | c.495C>T p.I165= | Silent (SNP) | VAF 11/133 reads (8%) | catalogued as rs747410517; called by muse, mutect2
- TTLL11 | c.1686G>A p.V562= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as rs1323961860; called by muse, mutect2, varscan2
- UBE3A | c.534G>A p.L178= | Silent (SNP) | VAF 51/126 reads (40%) | called by muse, mutect2, varscan2
- USP29 | c.27C>T p.F9= | Silent (SNP) | VAF 43/115 reads (37%) | called by muse, mutect2, varscan2
- VIRMA | c.1611C>G p.L537= | Silent (SNP) | VAF 113/220 reads (51%) | called by muse, mutect2, varscan2
- VN1R1 | c.519C>T p.L173= | Silent (SNP) | VAF 83/163 reads (51%) | catalogued as rs1318650945; called by muse, mutect2, varscan2
- VPS33B | c.408G>A p.V136= | Silent (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- XPC | c.2643A>G p.G881= | Silent (SNP) | VAF 35/65 reads (54%) | called by muse, mutect2, varscan2
- ZFP82 | c.393G>A p.E131= | Silent (SNP) | VAF 69/250 reads (28%) | called by muse, mutect2, varscan2
- ZNF124 | c.609G>A p.E203= (on ENST00000543802 / NM_001297568.1; = p.E141= on NM_003431.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/163 reads (23%) | called by muse, mutect2, varscan2
- ABCD4 | c.815-20C>T | Intron (SNP) | VAF 27/438 reads (6%) | called by muse, mutect2
- AC005324.2 | c.*174C>T | 3'UTR (SNP) | VAF 8/224 reads (4%) | catalogued as rs1418453491; called by muse, mutect2
- AC011487.2 | n.778A>T | RNA (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- AC079228.1 | n.356G>T | RNA (SNP) | VAF 72/177 reads (41%) | called by muse, mutect2, varscan2
- AC092818.1 | n.375T>A | RNA (SNP) | VAF 65/141 reads (46%) | called by muse, mutect2, varscan2
- AC231657.3 | c.*28G>A | 3'UTR (SNP) | VAF 19/21 reads (90%) | catalogued as rs1342907493; called by muse, mutect2, varscan2
- ACBD4 | c.89-96C>T | Intron (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- ADAMTS14 | c.*16C>G | 3'UTR (SNP) | VAF 25/103 reads (24%) | called by muse, mutect2, varscan2
- ADCY3 | c.*681C>T | 3'UTR (SNP) | VAF 40/48 reads (83%) | catalogued as rs1025762396; called by muse, mutect2, varscan2
- ADGRA1 | c.*592G>T | 3'UTR (SNP) | VAF 54/102 reads (53%) | called by muse, mutect2, varscan2
- ADGRF4 | chr6:47693704 C>T | 5'Flank (SNP) | VAF 13/308 reads (4%) | called by muse, mutect2
- ADH1B | c.568-10G>A | Intron (SNP) | VAF 38/215 reads (18%) | called by muse, mutect2, varscan2
- ADNP | chr20:50889632 C>T | 3'Flank (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2
- ADRA2B | c.*1861T>G | 3'UTR (SNP) | VAF 40/84 reads (48%) | called by muse, varscan2
- ADSL | c.655-14C>G | Intron (SNP) | VAF 125/261 reads (48%) | called by muse, mutect2, varscan2
- AFDN | c.2037+276G>A | Intron (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- AFG3L2 | c.*237C>T | 3'UTR (SNP) | VAF 33/71 reads (46%) | catalogued as rs754369427; called by muse, mutect2, varscan2
- AGO3 | c.-25C>G | 5'UTR (SNP) | VAF 61/133 reads (46%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825935 C>G | 5'Flank (SNP) | VAF 20/135 reads (15%) | called by muse, mutect2, varscan2
- AL359195.2 | chr10:80245318 C>T | 5'Flank (SNP) | VAF 129/292 reads (44%) | called by muse, mutect2, varscan2
- ALKBH5 | c.*720C>G | 3'UTR (SNP) | VAF 48/107 reads (45%) | catalogued as COSV101213238; called by muse, mutect2, varscan2
- AMD1 | c.*924G>A | 3'UTR (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- ANKLE2 | c.181+348G>A | Intron (SNP) | VAF 12/202 reads (6%) | called by muse, mutect2
- ANO3 | c.*497C>T | 3'UTR (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- ANO6 | c.-202G>A | 5'UTR (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- AP001496.3 | chr18:5238306 G>A | 3'Flank (SNP) | VAF 69/239 reads (29%) | called by muse, mutect2, varscan2
- AP1AR | c.-91C>T | 5'UTR (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- AQP1 | c.*235C>G | 3'UTR (SNP) | VAF 98/106 reads (92%) | called by muse, mutect2, varscan2
- ARIH1 | c.*416C>G | 3'UTR (SNP) | VAF 70/210 reads (33%) | called by muse, mutect2, varscan2
- ARL13B | c.*712G>A | 3'UTR (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- ARL8A | c.*387A>T | 3'UTR (SNP) | VAF 14/138 reads (10%) | called by mutect2, varscan2
- ASB8 | c.*469G>A | 3'UTR (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- ATRNL1 | c.*3753G>A | 3'UTR (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- C11orf96 | chr11:43943608 G>A | 3'Flank (SNP) | VAF 71/233 reads (30%) | called by muse, mutect2, varscan2
- C11orf96 | chr11:43944334 G>A | 3'Flank (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- C17orf100 | c.*675G>A | 3'UTR (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- CACNA1E | c.*6521C>G | 3'UTR (SNP) | VAF 45/138 reads (33%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.1351+90C>A | Intron (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- CACNG8 | c.*1651G>C | 3'UTR (SNP) | VAF 57/146 reads (39%) | called by muse, mutect2, varscan2
- CAMK2A | c.*47C>T | 3'UTR (SNP) | VAF 136/278 reads (49%) | catalogued as rs1040789311, COSV100652081; called by muse, mutect2, varscan2
- CAMSAP2 | chr1:200739772 G>A | 5'Flank (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- CCDC140 | n.860G>A | RNA (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- CCDC68 | chr18:54903847 G>A | 3'Flank (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- CCSER1 | c.*955C>T | 3'UTR (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2
- CCT5 | chr5:10250222 C>G | 5'Flank (SNP) | VAF 148/322 reads (46%) | called by muse, mutect2, varscan2
- CD40 | c.52-10C>G | Intron (SNP) | VAF 97/235 reads (41%) | called by muse, mutect2, varscan2
- CD8A | c.*580_*583del | 3'UTR (DEL) | VAF 41/84 reads (49%) | called by mutect2, pindel, varscan2
- CDA | c.*306C>G | 3'UTR (SNP) | VAF 53/219 reads (24%) | catalogued as rs1243079203; called by muse, mutect2, varscan2
- CDC7 | c.*1183G>C | 3'UTR (SNP) | VAF 30/34 reads (88%) | called by muse, mutect2, varscan2
- CDH18 | c.-210A>C | 5'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- CDK10 | c.161-134G>A | Intron (SNP) | VAF 22/33 reads (67%) | catalogued as rs1393022261; called by muse, mutect2, varscan2
- CDK20 | c.*322G>A | 3'UTR (SNP) | VAF 181/499 reads (36%) | called by muse, mutect2, varscan2
- CDK5R1 | c.*1556G>A | 3'UTR (SNP) | VAF 64/133 reads (48%) | called by muse, mutect2, varscan2
- CDKN2AIPNL | c.*327G>A | 3'UTR (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2, varscan2
- CEACAM6 | c.-18G>C | 5'UTR (SNP) | VAF 88/188 reads (47%) | catalogued as COSV52267117, COSV99555778; called by muse, varscan2
- CEP85L | c.1437+42C>T | Intron (SNP) | VAF 13/28 reads (46%) | catalogued as rs1340817332, COSV63828832; called by muse, mutect2, varscan2
- CERCAM | chr9:128420403 G>A | 5'Flank (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- CFAP92 | c.-130C>T | 5'UTR (SNP) | VAF 56/134 reads (42%) | called by muse, mutect2, varscan2
- CHML | c.*4824G>A | 3'UTR (SNP) | VAF 6/124 reads (5%) | catalogued as rs1455466593; called by muse, mutect2
- CHMP4B | c.*81G>A | 3'UTR (SNP) | VAF 59/113 reads (52%) | called by muse, mutect2, varscan2
- CHRM3 | c.*3331G>A | 3'UTR (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- CLEC14A | c.*232G>A | 3'UTR (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- CLEC1B | chr12:9992456 C>T | 3'Flank (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- CLEC9A | c.-58-124C>T | Intron (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- CLTCL1 | c.1522-54C>T | Intron (SNP) | VAF 22/24 reads (92%) | called by muse, mutect2, varscan2
- COA6 | chr1:234373503 C>T | 5'Flank (SNP) | VAF 149/478 reads (31%) | catalogued as rs776481481, COSV64017073; called by muse, mutect2, varscan2
- COL14A1 | c.5312-326C>G | Intron (SNP) | VAF 98/294 reads (33%) | called by muse, mutect2, varscan2
- CORIN | c.2068+103A>T | Intron (SNP) | VAF 79/162 reads (49%) | called by muse, mutect2, varscan2
- CPM | c.*639C>T | 3'UTR (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- CSMD1 | chr8:2936510 G>T | 3'Flank (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- CST8 | c.-123G>A | 5'UTR (SNP) | VAF 46/88 reads (52%) | called by muse, mutect2, varscan2
- CTF1 | c.*71C>T | 3'UTR (SNP) | VAF 24/48 reads (50%) | catalogued as COSV54410138; called by muse, mutect2, varscan2
- CYB5A | c.*169C>T | 3'UTR (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- DARS2 | c.*320G>T | 3'UTR (SNP) | VAF 26/95 reads (27%) | called by muse, mutect2, varscan2
- DCAF16 | c.*2664G>A | 3'UTR (SNP) | VAF 47/107 reads (44%) | catalogued as rs1172500993; called by muse, mutect2, varscan2
- DCC | c.-18G>A | 5'UTR (SNP) | VAF 21/48 reads (44%) | catalogued as rs748787755, COSV71438149; called by muse, mutect2, varscan2
- DENND11 | c.*1296G>A | 3'UTR (SNP) | VAF 63/66 reads (95%) | called by muse, mutect2, varscan2
- DIP2C | c.157+1672C>G | Intron (SNP) | VAF 24/72 reads (33%) | catalogued as rs1016792890; called by muse, mutect2, varscan2
- DLC1 | c.*481G>A | 3'UTR (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- DNAJC11 | c.-14G>A | 5'UTR (SNP) | VAF 133/293 reads (45%) | called by muse, mutect2, varscan2
- DPH3 | c.*340C>T | 3'UTR (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- DPM3 | c.-32+86C>T | Intron (SNP) | VAF 41/133 reads (31%) | called by muse, mutect2, varscan2
- DPP10 | c.*343C>A | 3'UTR (SNP) | VAF 52/116 reads (45%) | called by muse, mutect2, varscan2
- DUOX1 | c.2819-11C>G | Intron (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- ECHDC2 | c.122-2278G>C | Intron (SNP) | VAF 53/97 reads (55%) | called by muse, mutect2, varscan2
- EFNA5 | c.*735A>C | 3'UTR (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- EFNB2 | c.-122G>A | 5'UTR (SNP) | VAF 22/25 reads (88%) | called by muse, mutect2, varscan2
- EIF4B | c.*638G>T | 3'UTR (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- ELK4 | c.*7633C>T | 3'UTR (SNP) | VAF 26/140 reads (19%) | called by muse, mutect2, varscan2
- ELOVL2 | c.*280T>C | 3'UTR (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
- ERI1 | c.*2849G>A | 3'UTR (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- ERP29 | c.*131G>C | 3'UTR (SNP) | VAF 74/77 reads (96%) | called by muse, mutect2, varscan2
- EVL | c.1088+1268G>C | Intron (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- EXOC5 | c.*1292A>T | 3'UTR (SNP) | VAF 74/160 reads (46%) | called by muse, mutect2, varscan2
- FABP4 | c.-27G>C | 5'UTR (SNP) | VAF 90/186 reads (48%) | called by muse, mutect2, varscan2
- FAIM2 | c.*3431G>A | 3'UTR (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2, varscan2
- FAM199X | c.*5807C>T | 3'UTR (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- FAM8A1 | c.*1283C>T | 3'UTR (SNP) | VAF 10/15 reads (67%) | called by muse, mutect2, varscan2
- FAS | c.*1474G>C | 3'UTR (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- FDFT1 | chr8:11802488 C>G | 5'Flank (SNP) | VAF 53/203 reads (26%) | catalogued as rs1430486476; called by muse, mutect2, varscan2
- FER | c.*5957C>T | 3'UTR (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- FGFBP3 | c.-32C>T | 5'UTR (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- FZD4 | c.*1869C>T | 3'UTR (SNP) | VAF 32/64 reads (50%) | catalogued as rs1384417832; called by muse, mutect2, varscan2
- GADL1 | c.1250+1231A>C | Intron (SNP) | VAF 27/72 reads (38%) | catalogued as rs560924427; called by muse, mutect2, varscan2
- GALNT10 | c.1056+2470A>C | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, varscan2
- GALNT2 | c.*1359C>A | 3'UTR (SNP) | VAF 84/236 reads (36%) | called by muse, mutect2, varscan2
- GAPDH | c.236+61C>T | Intron (SNP) | VAF 39/288 reads (14%) | catalogued as rs746568927; called by muse, varscan2
- GBP5 | chr1:89272020 G>C | 5'Flank (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- GGACT | c.*365G>A | 3'UTR (SNP) | VAF 21/21 reads (100%) | called by muse, mutect2, varscan2
- GIMAP1 | c.*1088G>A | 3'UTR (SNP) | VAF 91/99 reads (92%) | called by muse, mutect2, varscan2
- GJA1 | c.*1563C>T | 3'UTR (SNP) | VAF 79/172 reads (46%) | called by muse, mutect2, varscan2
- GJC2 | c.*562G>A | 3'UTR (SNP) | VAF 39/258 reads (15%) | called by muse, mutect2, varscan2
- GMNC | c.*64G>A | 3'UTR (SNP) | VAF 119/230 reads (52%) | called by muse, mutect2, varscan2
- GRSF1 | c.357+268G>A | Intron (SNP) | VAF 21/141 reads (15%) | called by muse, mutect2, varscan2
- GTPBP4 | c.*2059G>A | 3'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- H2BC15 | chr6:27838370 G>A | 5'Flank (SNP) | VAF 32/82 reads (39%) | catalogued as rs765052099; called by muse, mutect2, varscan2
- H4C12 | c.-19G>C | 5'UTR (SNP) | VAF 78/174 reads (45%) | called by muse, mutect2, varscan2
- HNRNPM | c.*67A>C | 3'UTR (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- HNRNPU | chr1:244852325 C>G | 3'Flank (SNP) | VAF 9/177 reads (5%) | called by muse, mutect2
- HSPA12A | c.*1546C>T | 3'UTR (SNP) | VAF 27/114 reads (24%) | called by muse, mutect2, varscan2
- IGSF8 | chr1:160098625 C>T | 5'Flank (SNP) | VAF 34/109 reads (31%) | called by muse, mutect2, varscan2
- IL20 | chr1:206865661 C>T | 5'Flank (SNP) | VAF 23/299 reads (8%) | called by muse, mutect2
- IRF6 | c.*944G>A | 3'UTR (SNP) | VAF 123/195 reads (63%) | called by muse, mutect2, varscan2
- ISCA1 | c.-49G>A | 5'UTR (SNP) | VAF 86/176 reads (49%) | called by muse, mutect2, varscan2
- ITGA8 | c.*827C>T | 3'UTR (SNP) | VAF 33/69 reads (48%) | catalogued as rs1386455403; called by muse, mutect2, varscan2
- JPT2 | c.336+307G>A | Intron (SNP) | VAF 26/41 reads (63%) | called by muse, mutect2
- KCNK13 | c.-156C>T | 5'UTR (SNP) | VAF 49/92 reads (53%) | called by muse, mutect2, varscan2
- KCNMB4 | c.-101G>A | 5'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- KDM1A | c.-80G>A | 5'UTR (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- KDR | c.*1449G>C | 3'UTR (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- KIF13A | c.4477-73G>A | Intron (SNP) | VAF 17/610 reads (3%) | called by muse, mutect2
- KIF13B | c.2187+324C>T | Intron (SNP) | VAF 24/89 reads (27%) | catalogued as rs1046931092; called by muse, mutect2, varscan2
- KLHL2P1 | n.251G>A | RNA (SNP) | VAF 47/108 reads (44%) | catalogued as rs912643042; called by muse, mutect2, varscan2
- L3MBTL2 | c.*335C>T | 3'UTR (SNP) | VAF 56/114 reads (49%) | catalogued as rs1371090192; called by muse, mutect2, varscan2
- LDHC | c.*83G>C | 3'UTR (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- LDHC | chr11:18451366 G>A | 3'Flank (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- LINC00469 | chr17:73760988 C>G | 5'Flank (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- LINC00643 | n.581C>T | RNA (SNP) | VAF 12/171 reads (7%) | called by muse, mutect2
- LINC01591 | n.12C>T | RNA (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- LYNX1 | c.*1666C>G | 3'UTR (SNP) | VAF 97/210 reads (46%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+2422C>G | Intron (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- MAPKBP1 | c.*1929G>A | 3'UTR (SNP) | VAF 72/122 reads (59%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+278C>T | Intron (SNP) | VAF 24/52 reads (46%) | catalogued as rs1397360420; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85932G>A | Intron (SNP) | VAF 70/149 reads (47%) | catalogued as rs867347992, COSV72280205, COSV72283716; called by muse, mutect2, varscan2
- MASP2 | c.413-86G>C | Intron (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2, varscan2
- MAU2 | c.*1632C>T | 3'UTR (SNP) | VAF 150/355 reads (42%) | catalogued as rs901624348; called by muse, mutect2, varscan2
- MBP | c.576+993T>G | Intron (SNP) | VAF 23/76 reads (30%) | called by muse, mutect2, varscan2
- MDM4 | c.*7455C>G | 3'UTR (SNP) | VAF 47/146 reads (32%) | called by muse, mutect2, varscan2
- MED22 | c.*1351G>A | 3'UTR (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2, varscan2
- METTL16 | chr17:2415275 G>A | 3'Flank (SNP) | VAF 41/151 reads (27%) | catalogued as rs751948374; called by muse, mutect2
- MEX3C | c.*282G>C | 3'UTR (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- MGAT4A | c.*3012G>A | 3'UTR (SNP) | VAF 53/92 reads (58%) | called by muse, mutect2, varscan2
- MMP8 | c.*1187G>A | 3'UTR (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- MOB1A | c.-23C>T | 5'UTR (SNP) | VAF 50/91 reads (55%) | called by muse, mutect2, varscan2
- MOCOS | c.*3266C>T | 3'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- MRO | c.*966C>T | 3'UTR (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- MRO | c.-36C>T | 5'UTR (SNP) | VAF 42/107 reads (39%) | called by muse, mutect2, varscan2
- MTAP | c.813+6495G>C | Intron (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- MTMR9 | c.*610C>T | 3'UTR (SNP) | VAF 39/84 reads (46%) | called by muse, mutect2, varscan2
- MYCBPAP | c.-7C>T | 5'UTR (SNP) | VAF 45/92 reads (49%) | catalogued as COSV60409624; called by muse, mutect2, varscan2
- MZF1 | c.580+51G>A | Intron (SNP) | VAF 9/32 reads (28%) | catalogued as rs540811752; called by muse, mutect2, varscan2
- NAA50 | c.*2348G>T | 3'UTR (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- NAALAD2 | c.1075+104G>A | Intron (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.730G>C | RNA (SNP) | VAF 143/317 reads (45%) | called by muse, mutect2, varscan2
- NAPSA | c.469-64G>A | Intron (SNP) | VAF 28/48 reads (58%) | called by muse, mutect2
- NCEH1 | c.*749G>C | 3'UTR (SNP) | VAF 18/23 reads (78%) | called by muse, mutect2, varscan2
- NCK1 | c.226+2278G>A | Intron (SNP) | VAF 104/247 reads (42%) | called by muse, mutect2, varscan2
- NCKAP5 | c.*1206C>T | 3'UTR (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- NDUFV2 | c.-23G>A | 5'UTR (SNP) | VAF 33/55 reads (60%) | called by muse, mutect2, varscan2
- NEGR1 | c.*827G>A | 3'UTR (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- NEURL1B | c.*376G>A | 3'UTR (SNP) | VAF 70/154 reads (45%) | called by mutect2, varscan2
- NEXMIF | c.*358G>C | 3'UTR (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- NEXN | c.*117C>A | 3'UTR (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- NFKBIA | c.228-150G>A | Intron (SNP) | VAF 48/100 reads (48%) | called by muse, mutect2, varscan2
- NFKBIZ | c.1935+38C>T | Intron (SNP) | VAF 83/252 reads (33%) | called by muse, mutect2, varscan2
- NLGN1 | c.*5093G>A | 3'UTR (SNP) | VAF 33/43 reads (77%) | called by muse, mutect2, varscan2
- NMNAT3 | c.*261C>T | 3'UTR (SNP) | VAF 59/124 reads (48%) | called by muse, mutect2, varscan2
- NOG | c.-446G>A | 5'UTR (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- NOL4 | c.*1027C>T | 3'UTR (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-109732G>A | Intron (SNP) | VAF 70/161 reads (43%) | catalogued as rs749579779, COSV58447021, COSV58496498; called by muse, mutect2, varscan2
- NTRK2 | c.1585+6100G>C | Intron (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- OBSCN | c.5138-1429C>T | Intron (SNP) | VAF 27/64 reads (42%) | catalogued as rs543252699; called by muse, mutect2, varscan2
- ODF2 | chr9:128456054 G>A | 5'Flank (SNP) | VAF 55/107 reads (51%) | called by muse, mutect2, varscan2
- ODF2 | c.249+58C>G | Intron (SNP) | VAF 47/143 reads (33%) | called by muse, mutect2, varscan2
- OTOR | c.*123G>C | 3'UTR (SNP) | VAF 32/231 reads (14%) | called by muse, mutect2, varscan2
- PARK7 | c.*393G>A | 3'UTR (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- PAX1 | c.287-186C>T | Intron (SNP) | VAF 31/71 reads (44%) | catalogued as rs1476703854; called by muse, mutect2, varscan2
- PAX7 | c.-2G>C | 5'UTR (SNP) | VAF 72/162 reads (44%) | called by muse, mutect2, varscan2
- PBOV1 | c.*418C>T | 3'UTR (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- PCDHB16 | c.-724G>A | 5'UTR (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- PDHA1 | c.*208G>C | 3'UTR (SNP) | VAF 17/18 reads (94%) | called by muse, mutect2, varscan2
- PEA15 | c.-2-2989G>A | Intron (SNP) | VAF 105/146 reads (72%) | called by muse, mutect2, varscan2
- PGM3 | c.*4162C>T | 3'UTR (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- PGR | c.*8304C>T | 3'UTR (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- PGR | c.*331G>A | 3'UTR (SNP) | VAF 10/63 reads (16%) | catalogued as rs1379064490; called by muse, mutect2, varscan2
- PHKB | c.*1485G>A | 3'UTR (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- PIGK | c.*15G>A | 3'UTR (SNP) | VAF 26/228 reads (11%) | catalogued as rs1008319546; called by muse, mutect2
- PIGZ | c.*7G>A | 3'UTR (SNP) | VAF 119/183 reads (65%) | called by muse, mutect2, varscan2
- PIK3C2G | c.*11G>A | 3'UTR (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99851582; called by muse, mutect2, varscan2
- PLA2G4E | c.*772C>T | 3'UTR (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- PLCXD2 | c.-284C>T | 5'UTR (SNP) | VAF 69/131 reads (53%) | called by muse, mutect2, varscan2
- PLPBP | c.*740G>A | 3'UTR (SNP) | VAF 7/20 reads (35%) | called by muse, varscan2
- PLPP5 | c.635-192G>C | Intron (SNP) | VAF 95/243 reads (39%) | called by muse, mutect2, varscan2
- PMEL | c.-51-173G>A | Intron (SNP) | VAF 50/111 reads (45%) | called by muse, mutect2, varscan2
- PNMA1 | c.-46G>A | 5'UTR (SNP) | VAF 43/92 reads (47%) | catalogued as rs749977793; called by muse, mutect2, varscan2
- POLR2C | c.136+373G>A | Intron (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- PPP1R9A | c.*4731G>A | 3'UTR (SNP) | VAF 44/61 reads (72%) | catalogued as rs774178224; called by muse, mutect2, varscan2
- PPP2R1A | c.*1338G>A | 3'UTR (SNP) | VAF 27/114 reads (24%) | called by muse, mutect2, varscan2
- PRDM10 | c.*2081C>T | 3'UTR (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- PREX1 | c.*1249C>T | 3'UTR (SNP) | VAF 54/118 reads (46%) | catalogued as rs1015192696; called by muse, mutect2, varscan2
- PRR23B | c.-209G>A | 5'UTR (SNP) | VAF 67/188 reads (36%) | called by muse, mutect2, varscan2
- PRR33 | c.-269G>A | 5'UTR (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- PSAPL1 | c.*2141C>T | 3'UTR (SNP) | VAF 50/153 reads (33%) | called by muse, mutect2, varscan2
- PTAFR | chr1:28149649 G>A | 3'Flank (SNP) | VAF 28/57 reads (49%) | catalogued as rs995736148; called by muse, mutect2, varscan2
- PTGER3 | c.1077+481C>T | Intron (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
- PTH2R | c.*588C>G | 3'UTR (SNP) | VAF 46/96 reads (48%) | called by muse, mutect2, varscan2
- PTP4A2 | c.*1943G>A | 3'UTR (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
- RAB6B | c.*2783G>C | 3'UTR (SNP) | VAF 74/164 reads (45%) | called by muse, mutect2, varscan2
- RAI14 | c.*1029G>A | 3'UTR (SNP) | VAF 21/127 reads (17%) | catalogued as rs1395903893; called by muse, mutect2, varscan2
- RAPGEF3 | c.1596+671C>T | Intron (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- RARRES2P9 | n.275C>G | RNA (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- RBMS1 | c.-387C>T | 5'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- RDH11 | c.-1G>A | 5'UTR (SNP) | VAF 50/245 reads (20%) | called by muse, mutect2, varscan2
- REL | c.-280C>T | 5'UTR (SNP) | VAF 12/26 reads (46%) | called by muse, varscan2
- RFXANK | c.337+104G>T | Intron (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2
- RHOT1 | chr17:32141469 C>T | 5'Flank (SNP) | VAF 38/87 reads (44%) | called by muse, mutect2, varscan2
- RHPN1 | c.*919C>A | 3'UTR (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- RIMBP2 | c.2202+2466C>T | Intron (SNP) | VAF 9/232 reads (4%) | called by muse, mutect2
- RIPPLY3 | c.*332A>G | 3'UTR (SNP) | VAF 44/121 reads (36%) | called by muse, mutect2, varscan2
- RITA1 | chr12:113185715 G>A | 5'Flank (SNP) | VAF 48/56 reads (86%) | called by muse, mutect2, varscan2
- RNF11 | c.*1933C>T | 3'UTR (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
- RNF216 | c.1812-18C>T | Intron (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- RNFT2 | c.*343C>G | 3'UTR (SNP) | VAF 17/18 reads (94%) | called by muse, mutect2, varscan2
- ROBO2 | c.1971+10C>G | Intron (SNP) | VAF 40/82 reads (49%) | called by muse, mutect2, varscan2
- RORA | c.*5612G>C | 3'UTR (SNP) | VAF 47/107 reads (44%) | called by muse, mutect2, varscan2
- RORB-AS1 | n.886+852C>T | Intron (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2
- RPL27A | c.319-389G>A | Intron (SNP) | VAF 16/70 reads (23%) | catalogued as rs1253467557; called by muse, mutect2, varscan2
- RPL7 | c.539-107del | Intron (DEL) | VAF 10/21 reads (48%) | called by mutect2, varscan2
- RPS28 | c.88-77C>T | Intron (SNP) | VAF 61/146 reads (42%) | called by muse, mutect2, varscan2
- RSAD2 | c.*609A>G | 3'UTR (SNP) | VAF 27/28 reads (96%) | called by muse, mutect2, varscan2
- SALL1 | c.*776G>A | 3'UTR (SNP) | VAF 11/113 reads (10%) | catalogued as rs1010540336; called by muse, mutect2, varscan2
- SAV1 | c.*1479G>A | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- SEC14L2 | c.*1827G>A | 3'UTR (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- SEMA6A | c.*2046C>G | 3'UTR (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- SERPINH1 | c.954+282C>T | Intron (SNP) | VAF 14/36 reads (39%) | catalogued as rs1009233250; called by muse, mutect2
- SH2D3C | c.-16C>T | 5'UTR (SNP) | VAF 90/205 reads (44%) | called by muse, mutect2, varscan2
- SHC1 | chr1:154970742 del TT | 5'Flank (DEL) | VAF 92/302 reads (30%) | called by mutect2, pindel, varscan2
- SHISA2 | c.*794G>A | 3'UTR (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- SIX1 | chr14:60652455 C>T | 5'Flank (SNP) | VAF 41/166 reads (25%) | called by muse, mutect2, varscan2
- SLAMF9 | c.*44C>T | 3'UTR (SNP) | VAF 25/84 reads (30%) | catalogued as COSV100928170; called by muse, mutect2, varscan2
- SLC12A1 | c.629-531G>A | Intron (SNP) | VAF 26/67 reads (39%) | called by muse, mutect2, varscan2
- SLC25A20 | c.*518G>C | 3'UTR (SNP) | VAF 58/139 reads (42%) | called by muse, mutect2, varscan2
- SLC26A6 | c.434-27C>T | Intron (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- SLC26A6 | c.24-18C>G | Intron (SNP) | VAF 37/64 reads (58%) | catalogued as COSV50862445; called by muse, mutect2, varscan2
- SLC35F5 | c.-139G>A | 5'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- SLC36A3 | c.-44G>A | 5'UTR (SNP) | VAF 57/150 reads (38%) | called by muse, mutect2, varscan2
- SLC39A14 | chr8:22420363 G>A | 3'Flank (SNP) | VAF 56/137 reads (41%) | called by muse, mutect2, varscan2
- SLC5A3 | c.*7959C>G | 3'UTR (SNP) | VAF 30/55 reads (55%) | called by muse, mutect2, varscan2
- SLC66A1 | c.805-521G>A | Intron (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- SLCO5A1 | c.*447T>A | 3'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- SMC1A | c.2196+85C>T | Intron (SNP) | VAF 39/41 reads (95%) | catalogued as rs1431986685; called by muse, mutect2, varscan2
- SMTNL2 | c.*425G>C | 3'UTR (SNP) | VAF 58/128 reads (45%) | catalogued as rs1256460227; called by muse, mutect2, varscan2
- SNPH | c.*1326C>G | 3'UTR (SNP) | VAF 91/192 reads (47%) | called by muse, mutect2, varscan2
- SNX27 | c.*306C>T | 3'UTR (SNP) | VAF 85/133 reads (64%) | called by muse, mutect2, varscan2
- SOSTDC1 | c.-25C>T | 5'UTR (SNP) | VAF 76/95 reads (80%) | catalogued as COSV100194298; called by muse, mutect2, varscan2
- SPOCK2 | c.*2714C>G | 3'UTR (SNP) | VAF 54/106 reads (51%) | called by muse, mutect2, varscan2
- SPOCK2 | c.*2125C>A | 3'UTR (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- SRRM4 | c.*4042G>C | 3'UTR (SNP) | VAF 6/38 reads (16%) | catalogued as rs905680272; called by muse, mutect2, varscan2
- STEAP4 | c.*6014G>A | 3'UTR (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- STK3 | c.822+148C>A | Intron (SNP) | VAF 13/24 reads (54%) | catalogued as rs901496228; called by muse, mutect2, varscan2
- STRN | c.*2526C>T | 3'UTR (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- STX8 | c.-11G>A | 5'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2
- SUFU | c.*538C>T | 3'UTR (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
- SUPT7L | c.-211G>A | 5'UTR (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- SVIP | c.*2389C>T | 3'UTR (SNP) | VAF 53/103 reads (51%) | called by muse, mutect2, varscan2
- SYTL4 | c.1449+36G>C | Intron (SNP) | VAF 48/50 reads (96%) | called by muse, mutect2, varscan2
- TACC2 | c.8349-30G>A | Intron (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- TADA2A | c.284+19G>C | Intron (SNP) | VAF 24/197 reads (12%) | called by muse, mutect2, varscan2
- TAGAP | c.783+119T>C | Intron (SNP) | VAF 37/40 reads (93%) | called by muse, mutect2, varscan2
- TBC1D30 | c.*4518C>A | 3'UTR (SNP) | VAF 7/147 reads (5%) | called by muse, mutect2
- TBL1XR1 | c.*5335T>C | 3'UTR (SNP) | VAF 31/38 reads (82%) | called by muse, mutect2, varscan2
- TCF12 | c.1115-40G>A | Intron (SNP) | VAF 59/112 reads (53%) | called by muse, mutect2, varscan2
- TCF21 | c.*8+28G>C | Intron (SNP) | VAF 44/88 reads (50%) | catalogued as rs778134064; called by muse, mutect2, varscan2
- TENT4A | c.*322C>T | 3'UTR (SNP) | VAF 62/119 reads (52%) | called by muse, mutect2, varscan2
- TGFA | c.*1308G>A | 3'UTR (SNP) | VAF 142/324 reads (44%) | called by muse, mutect2, varscan2
- THEMIS | c.*1263G>A | 3'UTR (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- TLN2 | c.5736+491G>C | Intron (SNP) | VAF 71/171 reads (42%) | catalogued as COSV60888283; called by muse, mutect2, varscan2
- TLR6 | c.*410C>G | 3'UTR (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- TMEM121B | chr22:17122024 G>T | 5'Flank (SNP) | VAF 51/79 reads (65%) | called by muse, mutect2, varscan2
- TMEM215 | c.*2057G>T | 3'UTR (SNP) | VAF 7/47 reads (15%) | catalogued as COSV61364008; called by muse, mutect2, varscan2
- TMEM251 | c.-5C>G | 5'UTR (SNP) | VAF 37/98 reads (38%) | called by muse, mutect2, varscan2
- TMEM41B | c.368+59C>T | Intron (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2
- TMTC2 | c.-187G>A | 5'UTR (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- TPM4 | c.*48C>T | 3'UTR (SNP) | VAF 24/38 reads (63%) | called by muse, mutect2, varscan2
- TRIB1 | c.-431G>A | 5'UTR (SNP) | VAF 150/392 reads (38%) | called by muse, mutect2, varscan2
- TRIB1 | c.-430G>A | 5'UTR (SNP) | VAF 152/387 reads (39%) | called by muse, mutect2, varscan2
- TRIM14 | c.*1528C>T | 3'UTR (SNP) | VAF 51/108 reads (47%) | catalogued as rs904646522; called by muse, mutect2, varscan2
- TRIM2 | chr4:153336789 C>T | 3'Flank (SNP) | VAF 52/135 reads (39%) | called by muse, mutect2, varscan2
- TRIM36 | c.64-6084C>T | Intron (SNP) | VAF 11/71 reads (15%) | catalogued as rs1437541415; called by muse, mutect2, varscan2
- TRPM3 | c.184-256979G>A | Intron (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2, varscan2
- TSC22D2 | c.-380G>A | 5'UTR (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- TSKS | c.663+132C>A | Intron (SNP) | VAF 54/111 reads (49%) | called by muse, mutect2, varscan2
- TSPAN5 | c.*303G>A | 3'UTR (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- TUBA4A | c.4-675G>A | Intron (SNP) | VAF 219/443 reads (49%) | called by muse, mutect2, varscan2
- TXNL1 | c.*1030C>T | 3'UTR (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2
- UBAP2L | c.3168+527C>G | Intron (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- UBE2D1 | c.-189C>T | 5'UTR (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- UBL4A | c.*948G>A | 3'UTR (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- UCK1 | c.*644G>A | 3'UTR (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2
- UGT2B11 | c.*167G>A | 3'UTR (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- UNC5C | c.-9C>T | 5'UTR (SNP) | VAF 42/79 reads (53%) | called by muse, mutect2, varscan2
- UQCRB | c.*1007C>T | 3'UTR (SNP) | VAF 9/52 reads (17%) | catalogued as rs759193533; called by muse, mutect2, varscan2
- UVSSA | chr4:1391611 C>G | 3'Flank (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- VAPB | c.*4036G>A | 3'UTR (SNP) | VAF 7/138 reads (5%) | called by muse, mutect2
- VCP | chr9:35072701 C>T | 5'Flank (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- WDR26 | c.*1065G>A | 3'UTR (SNP) | VAF 11/99 reads (11%) | catalogued as rs572012946, COSV54357082; called by muse, mutect2, varscan2
- XIST | n.11020G>C | RNA (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- XKR5 | c.242+3426G>C | Intron (SNP) | VAF 34/69 reads (49%) | called by muse, mutect2, varscan2
- XRCC5 | c.*1085C>G | 3'UTR (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- YWHAB | c.300+18C>T | Intron (SNP) | VAF 9/20 reads (45%) | catalogued as rs754726003; called by muse, mutect2
- ZBTB40 | c.*1297G>A | 3'UTR (SNP) | VAF 39/81 reads (48%) | called by muse, mutect2, varscan2
- ZBTB43 | c.*955G>A | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- ZBTB7B | chr1:155017690 G>A | 3'Flank (SNP) | VAF 112/190 reads (59%) | called by muse, mutect2, varscan2
- ZDHHC14 | c.*175G>A | 3'UTR (SNP) | VAF 43/47 reads (91%) | called by muse, mutect2, varscan2
- ZEB2 | c.-69-33G>A | Intron (SNP) | VAF 17/139 reads (12%) | catalogued as rs1297132917; called by muse, mutect2, varscan2
- ZFP41 | c.*891C>T | 3'UTR (SNP) | VAF 60/129 reads (47%) | called by muse, mutect2, varscan2
- ZNF207 | c.-127C>T | 5'UTR (SNP) | VAF 72/149 reads (48%) | catalogued as rs751208024; called by muse, mutect2, varscan2
- ZNF501 | c.*1368G>A | 3'UTR (SNP) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- ZNF516 | c.*3767C>T | 3'UTR (SNP) | VAF 31/97 reads (32%) | called by muse, mutect2, varscan2
- ZNF69 | c.-133C>G | 5'UTR (SNP) | VAF 57/135 reads (42%) | called by muse, mutect2, varscan2
- ZNF7 | chr8:144847234 C>T | 3'Flank (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- ZNF710 | c.*2247G>A | 3'UTR (SNP) | VAF 6/8 reads (75%) | called by muse, mutect2, varscan2
- ZNF718 | c.-146G>A | 5'UTR (SNP) | VAF 60/126 reads (48%) | called by muse, mutect2
- ZNF720 | c.361+130C>G | Intron (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- ZNF720 | c.361+1326C>G | Intron (SNP) | VAF 136/271 reads (50%) | catalogued as rs763872668; called by muse, mutect2, varscan2
